Surgical pathology report (de-identified scan), TCGA case TCGA-EX-A449, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of North Carolina, specimen TCGA-EX-A449-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Left tube and ovary, abdominal mass, left salpingo-oophorectomy

- Ovary

- Metastatic endocervical adenocarcinoma with extensive necrosis

ICD-0-3

- Tumor measures 25 cm in greatest dimension

adenocarcinoma, endocervical type

8384/3

- Focal surface involvement is present

Site: cervix, NOS C53.9

lw 9/28/12

- Fallopian tube

- Detached endocervical adenocarcinoma in tubal lumen with focal involvement of tubal epithelium

- Benign paratubal cysts

B: Uterus, cervix, right tube and ovary, hysterectomy with right salpingo-oophorectomy

Location of tumor: endocervical origin with involvement of lower uterine segment, left adnexa, and right paratubal tissue

Histologic type: endocervical adenocarcinoma with villoglandular features

Reviewed by Lead pathologist
and deemed acceptable.

lw 9/20/12

Histologic grade: well differentiated

Extent of invasion: endocervical adenocarcinoma in situ involves the endocervix circumferentially with several foci of invasive endocervical adenocarcinoma largest invasive focus measures 6.5 mm in horizontal extent by 4 mm in depth

Stromal invasion: Inner half

Depth: 4 mm Wall thickness: 15 mm Percent: 27%

Serosal involvement: absent

Reviewed by Initials	EW	

[page 2 of 6]
Adnexal involvement (see above): present

Cervical/vaginal margin and distance: 8 mm from cervical margin; 9 mm from vaginal margin

Lymphovascular space invasion: none identified in submitted sections

Regional lymph nodes: no lymph nodes submitted

Other pathologic findings:

Cervix

- Cervical intraepithelial neoplasia 3 (CIN 3) involving the anterior cervix
- Chronic cervicitis

Endometrium

- Proliferative endometrium

Myometrium

- Multiple leiomyomas measuring up to 2.8 cm in greatest dimension
- Adenomyosis

AJCC Pathologic Stage: pT1b1 pNx pM1

FIGO (2008 classification) Stage grouping: IVB

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review.

Ovary, right, oophorectomy:

- Physiologic changes with multiple cystic follicles and hemorrhagic corpus luteum

Fallopian tube, right, salpingectomy:

- Paratubal tissue involved by metastatic endocervical adenocarcinoma
- Benign paratubal cysts

[page 3 of 6]
C: Omentum, omentectomy

- No tumor seen
- Mesothelial hyperplasia and chronic inflammation

Comment:

Immunohistochemical stains were performed and the endocervical and ovarian tumors are positive for CK7 and negative for CK20 and CDX2. All tumor foci are strongly and diffusely positive for p16 and positive for hrHPV by ISH. The tumor focus in the left fallopian tube is negative for p53. Morphology and immunostaining pattern are consistent with endocervical adenocarcinoma metastatic to the left adnexa and right paratubal tissue. Immunostains for p63 and CK5/6 confirm presence of squamous dysplasia.

Intraoperative Consult Diagnosis:

An intraoperative consult was requested by Drs. in OR 1 at (A) and (B) on

FSA1: Left tube and ovary, left salpingo-oophorectomy, representative sections

- Low malignant potential tumor, at least
- No evidence of metastatic melanoma

FSB1: Uterus, cervix, right tube and ovary, hysterectomy and right salpingo-oophorectomy

- Adenocarcinoma (representative section of cervix)

Drs. at

Frozen Section Pathologist:

Clinical History:

year-old female with history of stage III melanoma and a large abdominal mass.

Gross Description:

[page 4 of 6]
Received are three containers labeled appropriately for this patient. Specimens A and B are received fresh for frozen section.

Container A is additionally labeled "left tube and ovary and abdominal mass" and is received fresh for frozen section. The container holds a salpingo-oophorectomy specimen measuring 25 x 22 x 11.5 cm and weighing 900 grams. The ovarian serosal surface is primarily smooth with a few areas of nodularity. These areas are inked blue. Sectioning reveals the ovary replaced by a tumor mass with solid and cystic areas and filled with thick, yellow, mucinous material. Many solid areas have a stringy and friable quality and some are overtly necrotic. A fimbriated fallopian tube is present measuring 4 cm in length x 1 cm in width. There is a 2.5 cm paratubal cyst, but otherwise the fallopian tube is unremarkable.

Block Summary:

FSA1 - Frozen section remnant

A2-A3 - Sections of tumor from area suspicious for serosal surface involvement

A4-A6 - Tumor with residual normal ovarian parenchyma

A7-A14 - Representative sections of tumor

A15-A16 - Sections of fallopian tube away from the fimbriated end

A17 - Paratubal cyst

A18 - Fimbriated end

Container B is additionally labeled "uterus, cervix, right fallopian tube and ovary" and holds a hysterectomy and unilateral salpingo-oophorectomy specimen weighing in total 290 grams. The uterus measures as follows: height 12.5 cm, breadth at fundus 7.3 cm in anterior to posterior 4.8 cm. The anterior soft tissue margin around the cervix and lower uterine segment is inked green and posterior black.

The ectocervix has a white /tan and friable mass protruding through the os. Sectioning reveals a dilated endocervical canal filled with tumor. It appears similar to the ovarian tumor with copious mucinous discharge. The mass measures 4.9 cm in greatest height x at least 3.5 cm in width. It involves the entirety of the cervix, circumferentially. No significant parametrial tissue is present.

[page 5 of 6]
A vaginal cuff is also absent. The mass invades into but not through the cervical stroma being 0.6 cm from the inked soft tissue margin at closest approach. The mass extends up into the lower uterine segment.

The endometrium is red/brown and shaggy appearing in multiple areas. The thickness ranges from 0.3 to 0.7 cm. The myometrium is firm, white and trabeculated with multiple mural nodules reaching 2.8 cm maximal size. Sectioning reveals several of these myometrial nodules in the posterior corpus to have dark brown hemorrhagic contents and a multicystic appearance (size ranges from 0.9 to 1.2 cm). The uterine serosa appears smooth and intact with no grossly apparent tumor implants.

The right fallopian tube and ovary are present and inked blue. The ovary appears enlarged measuring 4 x 2 x 1.7 cm, with nodular protrusions on the serosal surface. The cross section shows normal variegated ovarian parenchyma with evidence of corpora lutea and small cystic areas filled with thin serosal fluid. Tumor tissue is not identified. There are solid hemorrhagic areas present. The right fallopian tube measures 7 cm in length x 1 cm in width. There is a 2.7 cm paratubal cyst. One area on the fallopian tube has a shaggy appearance, ?round ligament tissue vs. tumor. There is residual left fallopian tube present. Representative sections are submitted per block summary.

Block Summary:

FSB1 - Frozen section remnant

B2-B4 - One vertical section through the cervix, B2 most superior, B3 middle, B4 ectocervix, posterior cervix

B5-B6 - One vertical cross sectioned to posterior cervix, B5 superior, B6 with ectocervix

B7-B8 - One vertical cross sectioned to posterior cervix, B7 superior, B8 with ectocervix

B9-B11 - Vertical cross section through the tumor in anterior cervix, B9 superior, B10 middle, B11 ectocervix

B12 - Anterior ectocervix, with an area most suspicious for closest soft tissue margin

B13 - Anterior lower uterine segment

B14 - Posterior lower uterine segment

B15 - Anterior corpus, full thickness section

B16 - Anterior corpus endometrium, additional representative section

[page 6 of 6]
B17-B18 - Posterior corpus, full thickness section, bisected, endometrium in B17, hemorrhagic and cystic subserosal nodules in B18

B19-B20- Anterior corpus endometrium, representative sections (not full thickness)

B21-B23 - Representative sections of the right ovary

B24 - Right fallopian tube, area with shaggy appearance

B25 - Paratubal cyst, right tube

B26 - Fimbriated end

B27 - Left fallopian tube stump, representative section

Container C is additionally labeled "omentum" and holds a 29 x 18 cm sheet of lobulated adipose tissue with an average thickness of 2 cm. No areas suspicious for tumor infiltrations are identified grossly. Representative sections are submitted in blocks C1-C5.

Source: NCI Genomic Data Commons file 4c90bf0d-b56a-4afc-a65d-0d1283f97f3f (TCGA-EX-A449.C758E08B-3903-4C72-8F2D-5B064F24BCC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).